Gene-level copy-number profile of tumor specimen TCGA-AX-A1CA-01A from TCGA case TCGA-AX-A1CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 70.7 years (25,817 days).
Specimen TCGA-AX-A1CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.8551f90d-9c76-444d-8275-77fb7a24fd31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1CA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44324ee7-494b-44df-9c2f-8056ecf45232

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 2,575; copy number 2: 20,148; copy number 3: 16,555; copy number 4: 16,426; copy number 5: 3,180; copy number 6: 384; copy number 7: 141; copy number 8: 39; copy number 9: 71; copy number 10: 70; copy number 11: 2; copy number 12: 83; copy number 15: 5; copy number 16: 7; copy number 24: 3; copy number 26: 65; copy number 27: 20; copy number 35: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A1CA-01A-12D-A134-01): tumor purity 0.65, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,103,719–5,233,840, 4 genes: OR10AH1P, ZNF890P, RNU6-215P, WIPI2.
- chr7:89,443,946–89,496,918, 1 gene: AC002383.1.
- chr7:94,907,202–96,377,920, 25 genes (within-gene range 0–2): PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P.
- chr7:111,411,319–111,411,883, 1 gene: AC003989.1.
- chr7:121,873,089–122,062,036, 1 gene (within-gene range 0–2): PTPRZ1.
- chr7:127,346,790–127,431,924, 1 gene (within-gene range 0–2): ZNF800.
- chr7:127,476,883–127,485,804, 1 gene: AC000124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,073 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–186,988,981, 1,344 genes, copy number 5 (broad region; genes not listed).
- chr2:203,782,037–205,620,162, 13 genes, copy number 5 (within-gene range 4–5): RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1, AC008171.1.
- chr3:84,638,405–88,467,594, 36 genes, copy number 5: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA.
- chr3:134,313,576–134,375,479, 5 genes, copy number 6: LINC02004, AC010207.1, RPL39P5, AMOTL2, MIR6827.
- chr6:76,660,486–77,097,788, 2 genes, copy number 8: AL590426.1, AL355612.1.
- chr7:6,952,625–8,752,961, 30 genes, copy number 5 (within-gene range 2–5): AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1.
- chr7:9,614,978–11,832,198, 23 genes, copy number 5–35: GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3.
- chr7:12,726,152–14,071,380, 9 genes, copy number 9–26: AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:14,814,131–18,027,846, 44 genes, copy number 7–16: AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:18,127,220–18,127,309, 1 gene, copy number 16: MIR1302-6.
- chr7:21,215,537–36,841,373, 317 genes, copy number 6–12 (broad region; genes not listed).
- chr7:36,919,357–36,919,432, 1 gene, copy number 8: MIR1200.
- chr7:38,178,245–40,860,763, 60 genes, copy number 5–9 (within-gene range 2–9): STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1.
- chr7:49,760,897–50,121,329, 4 genes, copy number 7 (within-gene range 2–7): AC093775.1, VWC2, ZPBP, GNL2P1.
- chr8:29,048,494–30,385,401, 39 genes, copy number 6: RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1.
- chr8:43,093,498–43,674,591, 25 genes, copy number 7: POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr11:131,004,128–135,075,908, 55 genes, copy number 5: RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr13:44,234,118–44,256,596, 1 gene, copy number 5: AL589745.1.
- chr13:101,710,804–114,337,626, 195 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr16:4,180,117–4,355,607, 8 genes, copy number 5: AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1.
- chr16:4,346,694–4,348,648, 1 gene, copy number 5: AC012676.5.
- chr17:142,789–4,187,310, 164 genes, copy number 5 (broad region; genes not listed).
- chr17:4,163,910–4,186,424, 2 genes, copy number 5: AC087292.1, Y_RNA.
- chr17:21,428,263–21,574,517, 1 gene, copy number 5 (within-gene range 3–5): LINC02693.
- chr17:21,504,558–22,706,703, 42 genes, copy number 5: RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr19:27,638,483–30,228,715, 63 genes, copy number 26 (broad region; genes not listed).
- chr19:31,348,881–32,587,453, 19 genes, copy number 27: AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5.
- chr19:32,608,337–32,608,469, 1 gene, copy number 27: SNORA68B.
- chr19:33,555,568–33,773,509, 3 genes, copy number 24 (within-gene range 4–24): AC010485.1, RPL21P131, CHST8.
- chr19:34,254,552–58,605,223, 1,546 genes, copy number 5–10 (broad region; genes not listed).
- chr21:14,818,843–15,014,430, 2 genes, copy number 5 (within-gene range 3–5): AF127577.4, LINC02246.
- chr21:14,918,534–15,880,069, 17 genes, copy number 5: AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP.

Autosomal genes at a single copy (total copy number 1): 626. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
